BEATAML1.0 case 2203 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/bdc82843-8422-4e43-9312-b79ea6227353

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia with mutated NPM1: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.1 years (24,503 days); Progression or recurrence: yes; ELN risk classification: Intermediate.

Biospecimens (2 samples)
- Sample BA2552D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample BA2552R: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
